Surgical pathology report (de-identified scan), TCGA case TCGA-06-0646, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0646-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

TCGA-06-0646

CLINICAL HISTORY

[REDACTED] with recent onset seizure has a 3.0 cm. mass in the right middle temporal lobe, with recently developed enhancement, absent edema, and some satellite lesions.

OPERATIVE DIAGNOSES

Not Given

Operation/Specimen: A: Brain, temporal lobe, lobectomy
B: Brain, right temporal tumor, excision biopsy
C: Brain, right temporal tumorexcision biopsy
D: Brain, posterior resection margin excision biopsy

PATHOLOGICAL DIAGNOSIS:

A. Brain, temporal lobe, lobectomy: No diagnostic features.
B. Brain, right temporal, biopsy: Glioblastoma.
C. Brain, right temporal, excision: Glioblastoma.
D. Brain, posterior resection margin, excision: Cerebral cortex and white matter, free of neoplasm.
See Comment.

COMMENT

Part A is portions of cerebral cortex and adjacent white matter, in which there are focal areas of recent edema. There is no neoplasia.

Parts B and C are portions of cerebral cortex and adjacent white matter infiltrated and extensively effaced by a glial neoplastic proliferation with nuclear anaplasia, mitotic figures, microvascular cellular proliferation, and necrosis, some with pseudopalisading, i.e. a glioblastoma.

Part D is small fragments of unremarkable cerebral cortex and adjacent white matter devoid of neoplasm.

Special stains results will be reported as an addendum.

PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

[page 2 of 3]
NEGATIVE - No evidence of methylated MGMT promoter is detected.

Results-Comments

Testing was done on paraffin block

TEST DESCRIPTION: Bisulfite treatment of DNA followed by PCR amplification of both methylated and unmethylated MGMT promoter sequences, with products detected by gel electrophoresis.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

Interpretation

Brain, Immunohistochemistry: MIB-1 proliferation index 14%.
See Results and Comment (below).

Results-Comments

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates gliofibrillogenesis by the neoplastic cells, and frequent gemistocytes. Only about 3% of the neoplastic nuclei express the p53 mutant protein. With the MIB-1 there is a proliferation index of about 14% throughout the tumor.

Comment: The immunophenotype is consistent with a glioblastoma. The diagnosis remains unchanged.

INTRA-OPERATIVE CONSULTATION

B. Brain, touch prep and smears: Glioma with gemistocytic and anaplastic features. [REDACTED]

GROSS DESCRIPTION

A.

SPECIMEN: Temporal lobe.

FIXATIVE: Formalin.

GENERAL: Two, 1.5 x 1.4 x 1.3 cm and 5.0 x 4.5 x 2.5 cm segments of gray-tan brain tissue with a combined weight of 17.51 gm.

SECTIONS: A1 smallest fragment, entirely submitted, A2-A6 representative sections of larger fragments.

[page 3 of 3]
B.

SPECIMEN: Right temporal tumor

FIXATIVE: Formalin.

GENERAL: Received fresh, several fragments, 0.6 cm. in aggregate. Soft, grayish-pink, glistening. In total, B1.

C.

SPECIMEN: Right temporal tumor.

FIXATIVE: Formalin.

GENERAL: Received is an aggregate of tan-brown, slightly bosselated tissue, 3.5 x 2.2 x 1.5 cm. Cut surfaces are gray-white and unremarkable.

SECTIONS: Entirely submitted in C1-C3.

D.

SPECIMEN: Posterior resection margin.

FIXATIVE: None.

GENERAL: Received are multiple tan-brown fragments of bosselated tissue ranging from 0.2 to 0.7 cm greatest dimension.

SECTIONS: Entirely submitted in D1.

ICD-9(s):

191.2 191.2

Histo Data

Part A: Brain, temporal lobe, lobectomy

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
H/E x 1	1		
H/E x 1	2		
H/E x 1	3		
H/E x 1	4		
H/E x 1	5		
H/E x 1	6		

Part B: Brain, right temporal tumor, excision biopsy

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
mGFAP-DA x 1	1		
H/E x 1	1		
MGMT x 1	1		
MIB1-DA x 1	1		
P53DO7 x 1	1		

Part C: Brain, right temporal tumorexcision biopsy

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
H/E x 1	1		
H/E x 1	2		
H/E x 1	3		

Part D: Brain, posterior resection margin excision biopsy

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
H/E x 1	1		

Source: NCI Genomic Data Commons file 2bd59e87-cdc9-4a07-b030-ea5b37735fd0 (TCGA-06-0646.A087FE45-C2EB-4106-9C7A-AA0205CCDD73.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).